Gene-level copy-number profile of tumor specimen HTMCP-03-06-02109-01A from CGCI case HTMCP-03-06-02109, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3aaa0467-4aee-4421-b8aa-999b67b10516.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02109-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/9e5be392-c1c7-43ba-91ce-acfe98ef8cad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 1,432; copy number 2: 24,964; copy number 3: 21,049; copy number 4: 7,101; copy number 5: 2,350; copy number 6: 1,310; copy number 7: 89; copy number 8: 1; copy number 10: 62; copy number 11: 1; copy number 16: 6; copy number 79: 4; copy number 193: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,928,253, 11 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr17:46,274,784–46,509,339, 5 genes: ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,824 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,330,110–89,600,680, 2 genes, copy number 6: IGKV2-40, 5S_rRNA.
- chr3:119,146,151–129,606,676, 263 genes, copy number 5–193 (broad region; genes not listed).
- chr3:167,239,843–170,181,749, 54 genes, copy number 5: ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P.
- chr3:188,947,214–189,325,304, 1 gene, copy number 5 (within-gene range 4–5): TPRG1.
- chr3:189,238,686–190,322,446, 10 genes, copy number 5: TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1.
- chr3:196,142,525–196,341,715, 13 genes, copy number 5: LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P.
- chr5:58,198–32,791,724, 477 genes, copy number 5–11 (broad region; genes not listed).
- chr6:45,880,827–46,491,972, 8 genes, copy number 5: CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1.
- chr6:47,368,943–47,832,780, 12 genes, copy number 5–6: B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr7:142,507,382–142,802,748, 46 genes, copy number 5: TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr8:43,672,823–43,674,591, 2 genes, copy number 6: AC139365.2, AC139365.1.
- chr8:72,196,334–117,540,262, 644 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr8:118,189,455–145,066,685, 472 genes, copy number 5–6 (broad region; genes not listed).
- chr11:123,358,428–123,627,774, 1 gene, copy number 5 (within-gene range 2–5): GRAMD1B.
- chr12:52,069,246–52,108,261, 5 genes, copy number 10–79: ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1.
- chr13:110,305,812–114,337,626, 95 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:21,887,857–22,506,702, 82 genes, copy number 6–10 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.
- chr14:33,924,227–80,959,517, 888 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:88,384,924–88,627,596, 7 genes, copy number 5 (within-gene range 4–5): SPATA7, PTPN21, AL162171.2, RNU4-22P, AL162171.1, ZC3H14, AL162171.3.
- chr14:104,223,584–105,669,843, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:93,718,542–101,979,093, 177 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:39,665,349–39,730,532, 6 genes, copy number 16: TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1.
- chr20:87,250–24,446,314, 479 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
